Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YW, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YW-01A (Primary Tumor).

Patient

Surgical Pathology: Final

Surg Path

CLINICAL HISTORY:

Left parietal brain tumor.

GROSS EXAMINATION:

A. "Brain tumor (AF1)", received fresh for frozen section. A 0.6 x 0.6 x 0.5 cm aggregate of red-tan tissue is received. Two of the fragments have been previously submitted as frozen section AF1. The frozen section remnant is submitted in block A1. Representative retained in formalin and the remainder is submitted in block A2.

B. "Brain tumor", received fresh and placed in formalin. A 1.5 x 1 x 1 cm aggregate of pink-tan tissue is received. Representative retained in formalin and the remainder is submitted in blocks B1-B2.

INTRA OPERATIVE CONSULTATION:

A. "Brain tumor": AF1- glioma (Dr.

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a well differentiated glial neoplasm characterized by a population of astrocytes that are hyperchromatic and angulated intermixed with a population of cells with smaller and round nuclei, some of which show perinuclear clearing and appear to be oligodendroglial in origin. Cells in mitosis, microvascular proliferation, and necrosis are not identified. An immunohistochemical stain for the proliferation related Ki-67 (MIB-1) labeling index is low, 1-2%.

DIAGNOSIS:

A. "BRAIN TUMOR" (CRANIOTOMY):

OLIGOASTROCYTOMA (WHO GRADE II).

B. "BRAIN TUMOR" (CRANIOTOMY):

OLIGOASTROCYTOMA (WHO GRADE II).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed

ICD O-3
Oligoastrocytoma, grade II 9382/3
Site: Brain, supratentorial NOS C71.0
path 4 Brain NOS C71.9
7/5/14

Printed by:

Source: NCI Genomic Data Commons file f18c6b5c-6b00-4197-ad37-f76bd242bc6b (TCGA-E1-A7YW.821A037A-B968-4A91-9D3F-6DD2BD09B05F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).